Somatic mutation profile of tumor specimen ALCH-B210-TTP1-A (aliquot ALCH-B210-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B210, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 55.5 years (20,276 days).
Specimen ALCH-B210-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 692eb6da-ebd0-45de-ad8d-03da757f6be7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B210-NB1-A (Blood Derived Normal), aliquot ALCH-B210-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d1b2600-44af-4e29-9abe-06fda8a644fa

The open-access MAF lists 290 somatic variants for this specimen: 198 protein-altering or splice-affecting, 58 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, Silent 58, Intron 19, Nonsense Mutation 14, 5'Flank 7, Frame Shift Del 6, Splice Site 5, RNA 5, Splice Region 4, 3'UTR 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.423C>A p.C141* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | hotspot (GDC flag); catalogued as COSV52671863, COSV52706449, COSV52741627, COSV52827803; called by muse, mutect2, varscan2
- ADAMTS20 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs531290635, COSV101239486, COSV67131269; called by muse, mutect2, varscan2
- AFG1L | c.709G>T p.G237W | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934046; called by muse, varscan2
- APOB | c.2410C>T p.R804C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs749308859, COSV99264638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPM | c.4592G>T p.R1531L | Missense Mutation (SNP) | VAF 42/357 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs200681905, COSV54139741, COSV99660913; called by muse, mutect2, varscan2
- ATN1 | c.3137A>G p.N1046S | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.214); catalogued as rs782372541; called by muse, mutect2, varscan2
- ATP1A3 | c.2794G>A p.V932I (on ENST00000545399 / NM_001256214.2; = p.V919I on NM_152296.5) | Missense Mutation (SNP) | VAF 144/438 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as rs1568853008, COSV57488993; called by muse, varscan2
- ATP7B | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1331837177; called by muse, mutect2, varscan2
- CDH15 | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1330092752; called by muse, mutect2
- COL6A5 | c.5027C>A p.A1676E | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs776292131, COSV99592586; called by muse, mutect2
- COLGALT2 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV62731512; called by muse, mutect2, varscan2
- CSMD3 | c.3946C>T p.R1316C (on ENST00000297405 / NM_001363185.1; = p.R1212C on NM_052900.3) | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as rs1049829056, COSV52170361, COSV52249274, COSV52271911; called by muse, mutect2
- D2HGDH | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1341570111; called by muse, mutect2, varscan2
- DENND11 | c.983G>C p.R328P | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV101530705, COSV101530723; called by muse, mutect2, varscan2
- EHHADH | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.86); catalogued as rs1470269383; called by muse, mutect2, varscan2
- EIF2S3B | c.307C>G p.R103G | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.868); catalogued as rs763552453, COSV59370266; called by muse, mutect2, varscan2
- EPS8 | c.204+1G>A p.X68_splice | Splice Site (SNP) | VAF 15/135 reads (11%) | catalogued as COSV55535882; called by muse, mutect2, varscan2
- EXT1 | c.1797G>T p.W599C | Missense Mutation (SNP) | VAF 78/439 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM010235; called by muse, mutect2, varscan2
- FAM47C | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as COSV63723981; called by muse, mutect2
- FBXO40 | c.654G>T p.W218C | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57525498; called by muse, mutect2, varscan2
- GAS2L1 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99329647; called by muse, mutect2, varscan2
- GPR156 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs775980033; called by muse, mutect2, varscan2
- GRIN2A | c.3172C>A p.H1058N | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs988036800; called by muse, varscan2
- GYPC | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs149925576, COSV52146013; called by muse, mutect2, varscan2
- HCN1 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV100298017, COSV57531605; called by muse, mutect2, varscan2
- HEATR3 | c.1139C>G p.S380C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV53528986; called by muse, mutect2, varscan2
- HECW1 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs777261023, COSV67826494; called by muse, mutect2, varscan2
- HOXD1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs746068296; called by muse, mutect2, varscan2
- HTR5A | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as COSV55283584; called by muse, mutect2, varscan2
- KDM6A | c.2995G>T p.E999* | Nonsense Mutation (SNP) | VAF 39/189 reads (21%) | catalogued as COSV65038034, COSV65040758; called by muse, mutect2, varscan2
- KEAP1 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV50263782, COSV50281859; called by muse, mutect2, varscan2
- KIFAP3 | c.1935G>C p.K645N | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1226533594, COSV63034226; called by muse, varscan2
- KMT2C | c.591-1G>A p.X197_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | catalogued as COSV51288471, COSV51463672; called by muse, mutect2
- LRRK2 | c.3670G>T p.E1224* | Nonsense Mutation (SNP) | VAF 15/186 reads (8%) | catalogued as rs1401318314, COSV54147834; called by muse, mutect2
- MAGEC3 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT tolerated (0.65); PolyPhen benign (0.07); catalogued as rs773807636, COSV100025427; called by muse, mutect2, varscan2
- MPPED1 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as COSV68837761; called by muse, mutect2, varscan2
- NABP1 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 93/391 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as rs149409877; called by muse, mutect2, varscan2
- OR4D2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 20/487 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV73459712; called by muse, mutect2
- PCSK6 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373918878; called by muse, mutect2, varscan2
- PDE1B | c.1397C>G p.S466C | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs778369887; called by muse, mutect2, varscan2
- PGM5 | c.1229G>T p.R410L | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); catalogued as COSV67167563; called by muse, mutect2, varscan2
- PKHD1 | c.1832C>A p.T611K | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV61883206, COSV61891561; called by muse, mutect2, varscan2
- PLPPR3 | c.1750G>A p.D584N (on ENST00000520876 / NM_001270366.2; = p.D612N on NM_024888.2) | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1568282624; called by muse, mutect2, varscan2
- PRAMEF12 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV63214738; called by muse, mutect2, varscan2
- PRUNE2 | c.7460T>A p.V2487E | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1438325238; called by muse, varscan2
- PWWP3A | c.413C>T p.S138F (on ENST00000627377; = p.S137F on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.059); catalogued as rs753125041, COSV60900805; called by muse, mutect2, varscan2
- RGS17 | c.331C>A p.L111I | Missense Mutation (SNP) | VAF 53/528 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.083); catalogued as COSV99243293; called by muse, mutect2, varscan2
- RIT2 | c.345G>C p.E115D | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs750689156; called by muse, mutect2, varscan2
- RUNX1T1 | c.1786C>G p.P596A (on ENST00000265814 / NM_001198628.1; = p.P569A on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); catalogued as COSV99755836; called by muse, mutect2
- RYR1 | c.9750G>T p.M3250I | Missense Mutation (SNP) | VAF 90/180 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100617304; called by muse, mutect2, varscan2
- SERPINA4 | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as rs140397956, COSV100097396; called by muse, mutect2, varscan2
- SLC18B1 | c.501G>T p.L167F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV99259249; called by muse, varscan2
- SMPD1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs1554933790, CD042226; called by muse, mutect2, varscan2
- SMPD3 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs749212356, COSV54710973; called by muse, mutect2, varscan2
- SP8 | c.1447C>G p.P483A (on ENST00000361443 / NM_198956.4; = p.P501A on NM_182700.6) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV100815336; called by muse, mutect2, varscan2
- SRGAP3 | c.3133G>A p.A1045T | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.281); catalogued as rs894217708; called by muse, mutect2, varscan2
- SYNE1 | c.26301G>A p.M8767I (on ENST00000367255 / NM_182961.4; = p.M8719I on NM_033071.3) | Missense Mutation (SNP) | VAF 52/397 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.383); catalogued as rs1193879156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1042A>G p.M348V | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV99304831; called by muse, mutect2, varscan2
- TRAPPC9 | c.2810G>T p.R937L | Missense Mutation (SNP) | VAF 87/324 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV66896795, COSV66903195; called by muse, mutect2, varscan2
- TRHDE | c.1676A>G p.Y559C | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226508451; called by muse, mutect2, varscan2
- TRIM72 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.235); catalogued as rs1448803842; called by muse, mutect2, varscan2
- TSHZ1 | c.1708G>C p.A570P (on ENST00000580243 / NM_001308210.2; = p.A525P on NM_005786.6) | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV59015047; called by muse, mutect2, varscan2
- TTN | c.26654T>G p.L8885R (on ENST00000591111; = p.L7958R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | PolyPhen probably damaging (0.91); catalogued as COSV60071967; called by muse, mutect2, varscan2
- TTN | c.10666G>A p.D3556N (on ENST00000591111; = p.D3510N on NM_003319.4) | Missense Mutation (SNP) | VAF 48/628 reads (8%) | catalogued as COSV60404607; called by muse, mutect2
- TYR | c.1126C>A p.Q376K | Missense Mutation (SNP) | VAF 37/400 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as CM930719, COSV54482161; called by muse, mutect2
- UMODL1 | c.2995G>A p.V999I (on ENST00000408910 / NM_001004416.2; = p.V1127I on NM_173568.3) | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as rs902146857; called by muse, mutect2, varscan2
- USP34 | c.8135G>T p.R2712L | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV68405696; called by muse, mutect2, varscan2
- VSX2 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV99029628; called by muse, mutect2, varscan2
- WDR64 | c.2353C>A p.L785I | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV63798639; called by muse, mutect2
- WIPI2 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.144); catalogued as rs370098440, COSV104387260; called by muse, mutect2, varscan2
- YIPF7 | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV60656011; called by muse, mutect2
- ZNF511 | c.604del p.E202Rfs*33 (on ENST00000359035; = p.E202Rfs*100 on NM_145806.4) | Frame Shift Del (DEL) | VAF 30/166 reads (18%) | catalogued as rs1175144852; called by mutect2, pindel, varscan2
- ZNF836 | c.55C>G p.Q19E | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as COSV59084603; called by muse, mutect2, varscan2
- ABCC11 | c.2593G>T p.V865L | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- AC099552.1 | n.320G>T | Splice Region (SNP) | VAF 60/167 reads (36%) | called by muse, mutect2, varscan2
- ACO2 | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ADAMTS12 | c.2690C>A p.T897K | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- AHCTF1 | c.3407C>T p.A1136V (on ENST00000366508; = p.A1110V on NM_015446.5) | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- ALKBH8 | c.1378C>G p.R460G | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2
- ANKRD66 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO8 | c.2221T>A p.Y741N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- APBA3 | c.613del p.E205Rfs*59 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- ARHGAP19 | c.870C>G p.I290M | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2
- ARHGAP23 | c.1558C>G p.P520A | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP33 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATAT1 | c.1191G>T p.W397C (on ENST00000376485; = p.W385C on NM_001031722.4) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATR | c.1171-1G>T p.X391_splice | Splice Site (SNP) | VAF 26/348 reads (7%) | called by muse, mutect2
- BICD1 | c.1372A>G p.K458E | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- C7 | c.2443dup p.M815Nfs*3 | Frame Shift Ins (INS) | VAF 68/230 reads (30%) | called by mutect2, pindel, varscan2
- CABIN1 | c.457T>G p.C153G | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CACNA1A | c.3819C>A p.N1273K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- CBLN2 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCDC168 | c.18370G>C p.E6124Q | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CCDC168 | c.15816G>C p.E5272D | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CCDC65 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 10/341 reads (3%) | called by muse, mutect2
- CD2AP | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 54/414 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD86 | c.416C>A p.P139H (on ENST00000330540 / NM_175862.5; = p.P133H on NM_006889.4) | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDAN1 | c.3274G>T p.D1092Y | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- CEP250 | c.4369G>T p.A1457S | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CFAP99 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRNA6 | c.1148T>A p.L383H | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLSTN3 | c.1861G>T p.E621* | Nonsense Mutation (SNP) | VAF 29/151 reads (19%) | called by muse, mutect2, varscan2
- CLVS2 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- COL3A1 | c.3229G>T p.G1077C | Missense Mutation (SNP) | VAF 163/648 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.7181T>G p.V2394G (on ENST00000297405 / NM_001363185.1; = p.V2290G on NM_052900.3) | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.254); called by muse, mutect2
- DCSTAMP | c.631G>T p.G211C | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DDI1 | c.689C>G p.A230G | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DEPTOR | c.965C>A p.P322H | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- DHX58 | c.1463G>T p.R488L | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DLGAP2 | c.1270A>T p.K424* | Nonsense Mutation (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2
- DNAH3 | c.5762_5771del p.Y1921Cfs*8 | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | called by mutect2, pindel, varscan2
- DOCK2 | c.3257C>A p.P1086Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- DZIP3 | c.2930G>T p.R977I | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EPPK1 | c.4259G>T p.R1420L | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- F13B | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 28/194 reads (14%) | called by muse, mutect2, varscan2
- FRMD6 | c.369C>G p.I123M (on ENST00000344768 / NM_001267046.2; = p.I115M on NM_152330.4) | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GOLGA6L22 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.646); called by muse, mutect2
- GOLGA6L6 | c.1486C>A p.Q496K | Missense Mutation (SNP) | VAF 70/490 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, varscan2
- HADHB | c.1011G>A p.L337= | Splice Region (SNP) | VAF 47/506 reads (9%) | called by muse, mutect2
- HDHD5 | c.977A>T p.H326L (on ENST00000336737 / NM_033070.3; = p.H296L on NM_017829.5) | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- HOXB13 | c.42T>G p.D14E | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by mutect2, varscan2
- IFNAR2 | c.308_309del p.H103Rfs*32 | Frame Shift Del (DEL) | VAF 38/287 reads (13%) | called by pindel, varscan2
- IGHV4-59 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 137/905 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGKV2D-24 | c.5G>T p.R2M | Missense Mutation (SNP) | VAF 49/347 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA8 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ITPRID1 | c.1255T>A p.C419S | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- JAK2 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2, varscan2
- KALRN | c.5623C>A p.L1875I (on ENST00000360013 / NM_001024660.4; = p.L178I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); called by muse, mutect2
- LINGO1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- LRP1B | c.13003T>C p.C4335R | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LRP2 | c.13261G>T p.G4421* | Nonsense Mutation (SNP) | VAF 68/459 reads (15%) | called by muse, mutect2, varscan2
- LSM4 | c.22_27del p.K8_T9del | In Frame Del (DEL) | VAF 14/106 reads (13%) | called by mutect2, pindel, varscan2
- MACROD2 | c.1126T>G p.S376A (on ENST00000642719; = p.S348A on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.363); called by muse, mutect2
- MCOLN2 | c.67T>G p.L23V | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- METTL9 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIDEAS | c.1529C>A p.S510Y | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- MYH2 | c.929C>A p.P310Q | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO1A | c.2365C>G p.L789V | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- NEUROD6 | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUP210L | c.970T>G p.S324A | Missense Mutation (SNP) | VAF 55/363 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4D9 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- OR51I2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OTOA | c.208C>A p.H70N | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- PANK4 | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PCLO | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 98/313 reads (31%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PCMTD1 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, varscan2
- PDE1C | c.1324C>T p.L442F | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PDE3A | c.1899C>A p.S633R | Missense Mutation (SNP) | VAF 31/313 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2
- PGAM5 | c.193C>A p.R65= | Splice Region (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- PHLDB2 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PI4KA | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PKHD1L1 | c.4103C>G p.S1368C | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); called by muse, mutect2
- PLCXD3 | c.122G>T p.S41I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- PLEKHG4 | c.2777A>C p.Q926P | Missense Mutation (SNP) | VAF 83/323 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PNLIP | c.1030C>A p.L344I | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPP1R26 | c.2647G>C p.A883P | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.044); called by mutect2, varscan2
- PRSS56 | c.1702del p.A568Qfs*12 | Frame Shift Del (DEL) | VAF 27/102 reads (26%) | called by mutect2, pindel, varscan2
- PYGM | c.1056G>T p.R352S | Missense Mutation (SNP) | VAF 79/304 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RAD51D | c.739-2A>T p.X247_splice | Splice Site (SNP) | VAF 50/258 reads (19%) | called by muse, mutect2, varscan2
- RASAL2 | c.1649A>G p.E550G | Missense Mutation (SNP) | VAF 45/325 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFX6 | c.2002G>T p.V668L | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RPGRIP1L | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2
- SBNO1 | c.1526C>G p.A509G (on ENST00000420886; = p.A508G on NM_018183.5) | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- SCN4A | c.5196C>G p.I1732M | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- SEC31B | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SEC31B | c.1999G>T p.G667* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2
- SEMA6D | c.2747C>T p.S916F (on ENST00000316364 / NM_153618.2; = p.S854F on NM_020858.2) | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- SENP7 | c.2740G>C p.E914Q | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); called by muse, mutect2
- SIM1 | c.1517G>C p.R506T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC19A3 | c.891C>G p.N297K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC26A7 | c.429A>T p.Q143H | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SLC30A3 | c.579-3C>T | Splice Region (SNP) | VAF 50/186 reads (27%) | called by muse, mutect2, varscan2
- SLC9C2 | c.2356A>G p.K786E | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- SOGA3 | c.1717A>C p.K573Q | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- SPTBN5 | c.4329G>C p.Q1443H | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- TBC1D4 | c.1117A>C p.T373P | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- TEX50 | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TMC6 | c.431-1G>T p.X144_splice | Splice Site (SNP) | VAF 68/234 reads (29%) | called by muse, mutect2, varscan2
- TMEM114 | c.544del p.D182Tfs*34 | Frame Shift Del (DEL) | VAF 55/243 reads (23%) | called by mutect2, pindel, varscan2
- TMEM161B | c.781G>C p.A261P | Missense Mutation (SNP) | VAF 50/441 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- TNXB | c.6494G>A p.R2165K (on ENST00000647633; = p.R1918K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- TRIM49B | c.261C>A p.S87R | Missense Mutation (SNP) | VAF 54/389 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TRPA1 | c.3304A>T p.R1102* | Nonsense Mutation (SNP) | VAF 69/514 reads (13%) | called by muse, mutect2, varscan2
- TTC21B | c.2435T>G p.L812R | Missense Mutation (SNP) | VAF 58/606 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TTN | c.53356G>C p.V17786L (on ENST00000591111; = p.V10362L on NM_003319.4) | Missense Mutation (SNP) | VAF 44/508 reads (9%) | PolyPhen benign (0.001); called by muse, mutect2
- U2AF1L4 | c.595C>T p.H199Y (on ENST00000412391; = p.S140= on NM_144987.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- USP26 | c.717C>A p.C239* | Nonsense Mutation (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- VPS37B | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- WASF3 | c.644G>T p.R215I | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- WDR17 | c.2517G>T p.M839I | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- WWC1 | c.2779T>G p.S927A | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZFPL1 | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ZGRF1 | c.2509A>T p.T837S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- ZNF234 | c.1016C>A p.T339K | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ZNF257 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- ZNF618 | c.629A>C p.H210P (on ENST00000374126 / NM_001318042.2; = p.H178P on NM_133374.2) | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF76 | c.1495G>T p.V499F | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- ZNF804B | c.859C>A p.H287N | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AC131160.1 | c.525A>G p.A175= | Silent (SNP) | VAF 24/219 reads (11%) | called by muse, mutect2, varscan2
- ACSL1 | c.1530G>A p.V510= | Silent (SNP) | VAF 25/173 reads (14%) | catalogued as COSV99861059; called by muse, mutect2, varscan2
- AHRR | c.642G>A p.S214= | Silent (SNP) | VAF 36/182 reads (20%) | catalogued as rs766596616; called by muse, mutect2, varscan2
- ANO3 | c.2025C>T p.D675= | Silent (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- ASTN2 | c.3987C>A p.A1329= (on ENST00000313400 / NM_001365069.1; = p.A1278= on NM_014010.5) | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as COSV56006117; called by muse, mutect2, varscan2
- BCAT1 | c.610C>T p.L204= | Silent (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2, varscan2
- CARD11 | c.1719C>T p.I573= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as rs762267654, COSV62754698; called by muse, mutect2, varscan2
- CCDC88B | c.1026G>C p.R342= | Silent (SNP) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- CCN3 | c.132T>A p.P44= | Silent (SNP) | VAF 39/125 reads (31%) | called by muse, mutect2, varscan2
- CDH19 | c.2163C>T p.Y721= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as COSV50959351; called by muse, mutect2, varscan2
- CLSTN2 | c.1761C>T p.Y587= | Silent (SNP) | VAF 20/203 reads (10%) | called by muse, mutect2, varscan2
- CNNM1 | c.1206G>A p.R402= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as rs1378740791; called by muse, mutect2, varscan2
- COL6A5 | c.180C>A p.L60= | Silent (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- CRYBB1 | c.384G>A p.S128= | Silent (SNP) | VAF 55/409 reads (13%) | catalogued as rs370514627; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CSMD3 | c.8643A>T p.P2881= (on ENST00000297405 / NM_001363185.1; = p.P2712= on NM_052900.3) | Silent (SNP) | VAF 48/507 reads (9%) | called by muse, mutect2
- DNAH5 | c.11586G>T p.P3862= | Silent (SNP) | VAF 19/187 reads (10%) | catalogued as COSV54218580; called by muse, mutect2, varscan2
- DOHH | c.255C>T p.P85= | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2
- EBLN1 | c.1059A>T p.T353= | Silent (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2
- FAM166C | c.603A>C p.A201= | Silent (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2
- FBXL17 | c.552G>T p.P184= | Silent (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- GALNT2 | c.243T>C p.F81= | Silent (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.1656A>T p.A552= | Silent (SNP) | VAF 57/353 reads (16%) | called by muse, mutect2, varscan2
- GPR45 | c.1110T>C p.S370= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, varscan2
- GRID1 | c.2754G>T p.R918= | Silent (SNP) | VAF 62/285 reads (22%) | called by muse, mutect2, varscan2
- GRIN2B | c.2391C>T p.L797= | Silent (SNP) | VAF 37/278 reads (13%) | called by muse, mutect2, varscan2
- HAO1 | c.711C>A p.G237= | Silent (SNP) | VAF 32/338 reads (9%) | called by muse, mutect2, varscan2
- HLX | c.519C>T p.D173= | Silent (SNP) | VAF 31/195 reads (16%) | called by muse, mutect2, varscan2
- KCNC4 | c.414C>T p.T138= | Silent (SNP) | VAF 74/225 reads (33%) | called by muse, mutect2, varscan2
- LILRB2 | c.1575C>A p.A525= | Silent (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- LY96 | c.315C>T p.C105= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as rs1563714585; called by muse, mutect2
- MICAL2 | c.4158C>T p.I1386= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs377505982, COSV56288884; called by muse, mutect2, varscan2
- NCAPD3 | c.3042G>A p.K1014= | Silent (SNP) | VAF 20/156 reads (13%) | catalogued as rs1490863276; called by muse, mutect2, varscan2
- NDUFA4 | c.54C>G p.L18= | Silent (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2
- NEU4 | c.366G>A p.A122= (on ENST00000391969 / NM_001167602.3; = p.A134= on NM_080741.4) | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as rs373908190; called by muse, mutect2, varscan2
- NRM | c.45C>T p.F15= | Silent (SNP) | VAF 45/205 reads (22%) | catalogued as COSV51295438; called by muse, mutect2, varscan2
- NTN5 | c.327C>T p.P109= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs746359958, COSV54309043; called by muse, mutect2, varscan2
- NUP98 | c.3516C>T p.A1172= (on ENST00000359171 / NM_001365126.1; = p.A1155= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs776586304; called by muse, mutect2
- OR10W1 | c.111G>T p.V37= | Silent (SNP) | VAF 20/197 reads (10%) | catalogued as COSV67720330; called by muse, mutect2, varscan2
- OR51S1 | c.429C>A p.L143= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100437427; called by muse, mutect2, varscan2
- ORM1 | c.366C>T p.L122= | Silent (SNP) | VAF 18/147 reads (12%) | catalogued as rs1200683259; called by muse, mutect2, varscan2
- PAK3 | c.1380C>T p.I460= (on ENST00000262836 / NM_001324328.2; = p.I445= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 54/116 reads (47%) | called by muse, mutect2, varscan2
- PGR | c.2526G>A p.E842= | Silent (SNP) | VAF 26/168 reads (15%) | catalogued as COSV99051063; called by muse, mutect2, varscan2
- PHETA2 | c.321G>C p.A107= | Silent (SNP) | VAF 123/291 reads (42%) | catalogued as COSV58791203; called by muse, mutect2, varscan2
- PKD2L1 | c.1293C>T p.L431= | Silent (SNP) | VAF 27/221 reads (12%) | catalogued as rs543262797, COSV100559479; called by muse, mutect2, varscan2
- PLEKHG7 | c.1401C>T p.I467= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as rs1565795617, COSV60821662; called by muse, mutect2, varscan2
- PRB1 | c.270C>A p.P90= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV53706399; called by muse, mutect2, varscan2
- PRKCG | c.504C>A p.P168= | Silent (SNP) | VAF 81/166 reads (49%) | called by muse, mutect2, varscan2
- SH2B2 | c.180G>A p.P60= | Silent (SNP) | VAF 9/123 reads (7%) | catalogued as rs1468339240, COSV60826080; called by muse, mutect2
- SLC25A42 | c.90C>T p.H30= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as rs760156580; called by muse, mutect2, varscan2
- SLC30A7 | c.558A>T p.A186= | Silent (SNP) | VAF 19/177 reads (11%) | called by muse, mutect2, varscan2
- SNRPF | c.135A>C p.A45= | Silent (SNP) | VAF 18/200 reads (9%) | called by muse, mutect2
- TBKBP1 | c.687A>G p.L229= | Silent (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- TBXT | c.1230C>A p.I410= | Silent (SNP) | VAF 50/222 reads (23%) | catalogued as COSV51617290, COSV99752699; called by muse, mutect2, varscan2
- TNR | c.2499C>T p.G833= | Silent (SNP) | VAF 33/244 reads (14%) | catalogued as COSV54885545; called by muse, mutect2, varscan2
- TRIM58 | c.156C>A p.G52= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs1384925611, COSV63569146; called by muse, mutect2, varscan2
- U2AF1L4 | c.594C>T p.F198= (on ENST00000412391; = p.S140F on NM_144987.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/256 reads (16%) | catalogued as rs187720109; called by muse, mutect2, varscan2
- WDR17 | c.3582T>A p.R1194= | Silent (SNP) | VAF 15/158 reads (9%) | called by muse, mutect2
- ZNF700 | c.1257G>A p.E419= | Silent (SNP) | VAF 47/437 reads (11%) | catalogued as COSV54312649; called by muse, varscan2
- AC083864.1 | n.453C>T | RNA (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- ANKRD42 | c.138+48C>A | Intron (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- AP000769.3 | chr11:65503672 T>A | 5'Flank (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- APOOP5 | n.240T>A | RNA (SNP) | VAF 32/244 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP27 | c.658-4080G>T | Intron (SNP) | VAF 20/87 reads (23%) | called by muse, varscan2
- BAIAP2 | chr17:81031263 del C | 5'Flank (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- BTN2A3P | n.1448-363G>T | Intron (SNP) | VAF 26/196 reads (13%) | called by muse, mutect2, varscan2
- CCDC163 | c.330+39A>G | Intron (SNP) | VAF 51/216 reads (24%) | catalogued as rs369194488; called by muse, mutect2, varscan2
- CFAP44 | c.*4467T>A | 3'UTR (SNP) | VAF 38/209 reads (18%) | called by muse, mutect2, varscan2
- CYP21A2 | c.1119-31C>A | Intron (SNP) | VAF 40/184 reads (22%) | called by mutect2, varscan2
- DCUN1D4 | c.616-2109C>T | Intron (SNP) | VAF 36/289 reads (12%) | called by muse, mutect2, varscan2
- DPP9 | c.1945-165G>T | Intron (SNP) | VAF 29/145 reads (20%) | called by muse, mutect2, varscan2
- EHMT1 | c.*9C>T | 3'UTR (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- ERCC3 | c.1946-11T>G | Intron (SNP) | VAF 37/271 reads (14%) | called by muse, mutect2, varscan2
- EXOC3 | chr5:442571 A>G | 5'Flank (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- FOXL2NB | c.220+73C>T | Intron (SNP) | VAF 7/79 reads (9%) | catalogued as rs1440082310; called by muse, mutect2
- GCNT2 | c.926-34875G>T | Intron (SNP) | VAF 29/175 reads (17%) | called by muse, mutect2, varscan2
- GCNT2 | c.926-34874G>T | Intron (SNP) | VAF 29/177 reads (16%) | catalogued as rs770073300; called by muse, mutect2, varscan2
- IGLV8OR8-1 | n.101G>A | RNA (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- KRT18P55 | n.816G>T | RNA (SNP) | VAF 49/187 reads (26%) | called by muse, mutect2, varscan2
- MRPL3 | c.630-7922C>T | Intron (SNP) | VAF 32/274 reads (12%) | catalogued as rs753470158; called by muse, mutect2, varscan2
- MYH9 | c.706-51G>A | Intron (SNP) | VAF 69/216 reads (32%) | catalogued as rs772111672; called by muse, mutect2, varscan2
- OR2P1P | chr6:29076344 C>G | 5'Flank (SNP) | VAF 16/145 reads (11%) | called by muse, mutect2, varscan2
- PSMA6 | c.254-504C>A | Intron (SNP) | VAF 20/282 reads (7%) | called by muse, mutect2
- RGS6 | c.1368+10958C>T | Intron (SNP) | VAF 71/249 reads (29%) | called by muse, mutect2, varscan2
- SCAMP1 | c.-13G>A | 5'UTR (SNP) | VAF 44/120 reads (37%) | catalogued as rs777816777; called by muse, mutect2, varscan2
- SHTN1 | c.112-5195A>C | Intron (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- SNORD116-3 | n.23A>G | RNA (SNP) | VAF 35/263 reads (13%) | catalogued as rs531021559; called by muse, mutect2, varscan2
- STIP1 | chr11:64185953 C>T | 5'Flank (SNP) | VAF 32/122 reads (26%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2719+1057G>T | Intron (SNP) | VAF 41/436 reads (9%) | called by muse, mutect2
- TNFRSF4 | c.269-275G>C | Intron (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4869A>T | Intron (SNP) | VAF 28/253 reads (11%) | called by muse, mutect2, varscan2
- ZNF280D | chr15:56733649 C>A | 5'Flank (SNP) | VAF 18/94 reads (19%) | catalogued as COSV50996543; called by muse, mutect2, varscan2
- ZNF578 | chr19:52451447 C>A | 5'Flank (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
